Somatic mutation profile of tumor specimen MP2PRT-PAWAFX-TMP1-A (aliquot MP2PRT-PAWAFX-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAWAFX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,501 days).
Specimen MP2PRT-PAWAFX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c742b4a8-5e99-4b87-ae43-226c3035b0e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWAFX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWAFX-NB1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/317795b3-092e-4b4a-89c6-d0142a7ac063

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 5, Silent 4, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRIK2 | c.1372C>T p.R458* | Nonsense Mutation (SNP) | VAF 11/332 reads (3%) | catalogued as rs1271066576, COSV59710025; called by muse, mutect2
- PKP3 | c.1084G>C p.A362P | Missense Mutation (SNP) | VAF 93/322 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV100520740; called by muse, mutect2, varscan2
- PRPF39 | c.941T>C p.I314T | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs749790624; called by muse, mutect2
- TEX44 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 34/598 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs146402789; called by muse, mutect2
- CDKN2A | c.258_271delinsAGG p.R87Gfs*29 | Frame Shift Del (DEL) | VAF 199/945 reads (21%) | called by pindel, varscan2*
- IGHV1-45 | chr14:106506992 del TGTGTATCT | Missense Mutation (DEL) | VAF 20/113 reads (18%) | called by pindel*, varscan2
- TCTE1 | c.17C>T p.T6M | Missense Mutation (SNP) | VAF 77/302 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MFSD6L | c.180C>G p.A60= | Silent (SNP) | VAF 134/486 reads (28%) | called by muse, mutect2, varscan2
- PTGIS | c.1113C>T p.D371= | Silent (SNP) | VAF 56/642 reads (9%) | catalogued as rs561620152, COSV54836179; called by muse, mutect2
- RIPOR1 | c.1035C>T p.F345= (on ENST00000379312 / NM_001193522.2; = p.F341= on NM_024519.4) | Silent (SNP) | VAF 100/334 reads (30%) | called by muse, varscan2
- SCARA3 | c.21C>T p.G7= | Silent (SNP) | VAF 89/340 reads (26%) | catalogued as rs764823470, COSV57270615; called by muse, mutect2, varscan2
